Somatic mutation profile of tumor specimen MMRF_1201_4_BM_CD138pos (aliquot MMRF_1201_4_BM_CD138pos_T1_KHS5U_L15710) from MMRF case MMRF_1201, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,577 days).
Specimen MMRF_1201_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 939bc34c-1482-4cf4-8166-501cc486aec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1201_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1201_1_PB_WBC_C3_KBS5U_L02857; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa0b66dd-fa71-425d-9985-656d84222585

The open-access MAF lists 183 somatic variants for this specimen: 71 protein-altering or splice-affecting, 28 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 46, Intron 28, Silent 28, Nonsense Mutation 10, Splice Site 4, 3'Flank 4, In Frame Del 3, 5'UTR 3, Frame Shift Ins 2, 5'Flank 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BOD1L1 | c.3029C>A p.T1010N | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV50007242; called by muse, mutect2
- CASP1 | c.338-1G>T p.X113_splice (on ENST00000436863 / NM_033292.4; = p.X92_splice on NM_001223.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 27/46 reads (59%) | catalogued as COSV62057641; called by muse, mutect2, varscan2
- CECR2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | catalogued as rs1000953634, COSV52847831; called by muse, mutect2, varscan2
- CHRNA4 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs375524982, CM1212665, COSV64719127; called by muse, mutect2, varscan2
- CSMD3 | c.4339G>A p.V1447I (on ENST00000297405 / NM_001363185.1; = p.V1343I on NM_052900.3) | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as rs559028004; called by muse, mutect2, varscan2
- CUX1 | c.4483G>T p.A1495S | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99473516; called by muse, mutect2
- FECH | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs138138618; called by muse, mutect2, varscan2
- GBP3 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs145016759; called by muse, mutect2, varscan2
- HIVEP2 | c.2674C>T p.R892* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV50059289; called by muse, mutect2
- HOXA1 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1207189382, COSV58029150; called by muse, mutect2, varscan2
- HTR1B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs750400332, COSV64051170; called by muse, mutect2, varscan2
- IGHJ5 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 34/48 reads (71%) | PolyPhen benign (0.086); catalogued as rs781822844; called by muse, varscan2
- IGHV2-70 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs368209907; called by muse, varscan2
- IGLL5 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs749763264, COSV73251006, COSV73251200; called by muse, mutect2, varscan2
- MEF2A | c.258+8A>G | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as rs1220802225; called by muse, mutect2, varscan2
- MEGF8 | c.3422G>A p.W1141* (on ENST00000251268 / NM_001271938.2; = p.W1074* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 52/157 reads (33%) | catalogued as rs200096403, COSV52094945, COSV99236719; called by muse, mutect2, varscan2
- MYLIP | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.331); catalogued as COSV62767092; called by muse, mutect2, varscan2
- PCLO | c.15254G>A p.R5085Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569045178, COSV61643507, COSV61654875; called by muse, mutect2, varscan2
- PNMA2 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs769441970; called by muse, mutect2, varscan2
- RIT2 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 62/125 reads (50%) | catalogued as rs777127147, COSV100449455, COSV58676103; called by muse, mutect2, varscan2
- SCN11A | c.4433G>A p.R1478Q | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs758597298, COSV56577794; ClinVar: uncertain significance; called by muse, varscan2
- TSHZ1 | c.2429T>A p.I810N (on ENST00000580243 / NM_001308210.2; = p.I765N on NM_005786.6) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV59016143; called by muse, mutect2
- TTN | c.93496G>A p.D31166N (on ENST00000591111; = p.D23742N on NM_003319.4) | Missense Mutation (SNP) | VAF 147/270 reads (54%) | PolyPhen benign (0.274); catalogued as COSV60236264; called by muse, mutect2, varscan2
- ANKRD12 | c.2186A>T p.N729I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARID2 | c.627_629del p.F210del | In Frame Del (DEL) | VAF 42/88 reads (48%) | called by mutect2, varscan2
- ATP8B1 | c.393+1G>A p.X131_splice | Splice Site (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- CBY3 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CCN2 | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.508); called by muse, mutect2
- CDHR1 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL21A1 | c.2447A>C p.N816T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CTU2 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CXCR2 | c.718A>C p.K240Q | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2
- DDX42 | c.2023A>C p.N675H | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DPPA2 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- DTX1 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYRK1A | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); called by muse, mutect2
- GFOD1 | c.104C>G p.T35R | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HIVEP2 | c.933T>A p.Y311* | Nonsense Mutation (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- HSD17B3 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKC | c.322dup p.*108= | Frame Shift Ins (INS) | VAF 74/184 reads (40%) | called by mutect2, pindel, varscan2
- JMJD1C | c.4645A>T p.K1549* | Nonsense Mutation (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- KHSRP | c.277del p.A93Pfs*4 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | called by mutect2, pindel
- MACF1 | c.1326C>A p.N442K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2
- MPP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCAPH | c.596-2A>C p.X199_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- NCOR1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- OGT | c.1803_1809delinsA p.F601_V603delinsL | In Frame Del (DEL) | VAF 61/61 reads (100%) | called by pindel, varscan2*
- PIK3C2G | c.1727dup p.V578Gfs*5 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, varscan2
- PTPRQ | c.2244A>G p.I748M (on ENST00000616559; = p.I706M on NM_001145026.2) | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRQ | c.2335T>C p.Y779H (on ENST00000616559; = p.Y737H on NM_001145026.2) | Missense Mutation (SNP) | VAF 92/190 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.963); called by muse, varscan2
- PTPRZ1 | c.3920A>T p.K1307I | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2
- PURA | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 113/199 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP2B | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- RHOT2 | c.222+6C>T | Splice Region (SNP) | VAF 128/348 reads (37%) | called by muse, mutect2, varscan2
- RSRP1 | c.416_430del p.Y139_R144delinsC | In Frame Del (DEL) | VAF 58/163 reads (36%) | called by pindel, varscan2
- SALL1 | c.3892G>A p.E1298K | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- SALL3 | c.3307G>C p.A1103P | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SERTAD4 | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 23/490 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2
- SHTN1 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.344); called by muse, mutect2
- SIGLEC9 | c.387T>A p.N129K | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- SLC39A7 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.047); called by muse, mutect2
- SORL1 | c.6189G>A p.M2063I | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SPATA19 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 9/61 reads (15%) | called by pindel, varscan2*
- TAMM41 | c.701G>A p.W234* | Nonsense Mutation (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- TFAP2C | c.694T>C p.S232P | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM14B | c.53A>C p.Y18S | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNPO3 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TYW3 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 7/203 reads (3%) | called by muse, mutect2
- ZNF217 | c.1877T>G p.L626* | Nonsense Mutation (SNP) | VAF 119/255 reads (47%) | called by muse, mutect2, varscan2
- ABL1 | c.165C>T p.L55= | Silent (SNP) | VAF 82/165 reads (50%) | catalogued as rs1028031620; called by muse, mutect2, varscan2
- AKAP6 | c.5136G>A p.P1712= | Silent (SNP) | VAF 87/190 reads (46%) | catalogued as rs375264170; called by muse, mutect2, varscan2
- CSMD3 | c.8091C>T p.I2697= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as rs753078472, COSV52176951, COSV52233393; called by muse, mutect2, varscan2
- DCAF15 | c.1371C>A p.V457= | Silent (SNP) | VAF 8/226 reads (4%) | called by muse, mutect2
- FAM53A | c.1158C>T p.A386= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as rs764172167; called by muse, mutect2, varscan2
- FHOD3 | c.1056C>T p.G352= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs142186343; called by muse, mutect2, varscan2
- FOXRED2 | c.1554G>A p.G518= | Silent (SNP) | VAF 62/106 reads (58%) | catalogued as rs1214081729; called by muse, mutect2, varscan2
- GART | c.1350G>A p.L450= | Silent (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- GFPT2 | c.822C>T p.V274= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- GNAO1 | c.399C>T p.G133= | Silent (SNP) | VAF 103/196 reads (53%) | catalogued as rs556058539, COSV52612417; called by muse, mutect2, varscan2
- IGHV2-70D | c.303T>G p.L101= | Silent (SNP) | VAF 62/78 reads (79%) | called by muse, varscan2
- INTS8 | c.345A>C p.L115= | Silent (SNP) | VAF 21/391 reads (5%) | called by muse, mutect2
- KAT2B | c.897T>A p.P299= | Silent (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- LRRC66 | c.2589C>T p.P863= | Silent (SNP) | VAF 95/256 reads (37%) | catalogued as rs928416573; called by muse, mutect2, varscan2
- MMP15 | c.1419G>A p.E473= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MTFMT | c.201C>T p.H67= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs1244223902; called by muse, mutect2
- MYH1 | c.4653A>T p.A1551= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- MYH6 | c.3696C>T p.D1232= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs779525060; called by muse, varscan2
- OR4C12 | c.867T>C p.N289= | Silent (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- POLR3B | c.45G>A p.Q15= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- RFPL3 | c.582G>A p.L194= (on ENST00000249007 / NM_001098535.1; = p.L165= on NM_006604.2) | Silent (SNP) | VAF 17/396 reads (4%) | called by muse, mutect2
- SFXN5 | c.84C>T p.G28= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- SLC9A4 | c.1278C>T p.Y426= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- SNRNP200 | c.1542G>A p.L514= | Silent (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2, varscan2
- SPECC1 | c.2322C>T p.G774= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as rs1392496591; called by muse, mutect2
- STXBP5L | c.1707T>C p.P569= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- SYDE1 | c.1071C>T p.F357= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- TSC22D1 | c.189G>C p.L63= | Silent (SNP) | VAF 80/99 reads (81%) | called by muse, mutect2, varscan2
- AC125421.2 | chr17:73828496 A>T | 3'Flank (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- ACSL6 | c.1783-116T>C | Intron (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- ADAM28 | c.47-55G>C | Intron (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- ADGRL4 | c.*187G>T | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.*1579G>A | 3'UTR (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- AMPH | c.1183-1410C>G | Intron (SNP) | VAF 64/146 reads (44%) | called by muse, mutect2, varscan2
- ARL5A | c.*223G>A | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- BRD2 | c.-1112T>G | 5'UTR (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- BTG3 | c.*286C>T | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- C12orf56 | c.*228C>A | 3'UTR (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- C12orf77 | n.612+213T>G | Intron (SNP) | VAF 49/94 reads (52%) | called by muse, mutect2, varscan2
- C1orf115 | c.*558G>A | 3'UTR (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- CACNA1D | c.2811+91C>T | Intron (SNP) | VAF 66/163 reads (40%) | catalogued as rs570064228; called by muse, mutect2, varscan2
- CACNB2 | c.120+235G>C | Intron (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- CALN1 | c.*5919A>C | 3'UTR (SNP) | VAF 30/105 reads (29%) | called by muse, mutect2, varscan2
- CCDC58 | c.*174A>C | 3'UTR (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- CCNC | c.346+1079A>T | Intron (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- CCSAP | c.*1512A>T | 3'UTR (SNP) | VAF 37/166 reads (22%) | called by muse, mutect2, varscan2
- CDH8 | c.1536+90A>C | Intron (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- CDH9 | c.*454T>C | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- CHM | c.*1144T>C | 3'UTR (SNP) | VAF 15/15 reads (100%) | called by muse, mutect2, varscan2
- CLDN1 | c.*320_*329del | 3'UTR (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- CLN8 | c.*4586C>T | 3'UTR (SNP) | VAF 47/109 reads (43%) | catalogued as rs538474232; called by muse, mutect2, varscan2
- CREG1 | c.*72A>C | 3'UTR (SNP) | VAF 47/432 reads (11%) | called by muse, mutect2, varscan2
- CSK | c.722+28T>G | Intron (SNP) | VAF 64/167 reads (38%) | called by muse, mutect2, varscan2
- CTPS1 | c.1691+25A>T | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- DCBLD2 | c.*1826A>C | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- DDI1 | c.*195C>A | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- DENND6A | c.*2606T>A | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- DEPDC5 | c.1666+690A>C | Intron (SNP) | VAF 6/61 reads (10%) | catalogued as COSV56710190; called by muse, mutect2
- DUS2 | c.-18-85C>G | Intron (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- EBAG9 | c.429+782T>A | Intron (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- EN2 | c.*1058G>A | 3'UTR (SNP) | VAF 68/130 reads (52%) | called by muse, mutect2, varscan2
- F2RL2 | c.*43T>C | 3'UTR (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2, varscan2
- FAM13A | c.605+562G>C | Intron (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- FAM155A | c.*247G>C | 3'UTR (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- FAM169B | n.614C>T | RNA (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- FLRT2 | chr14:85529921 G>C | 5'Flank (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- FRG2C | c.*1026C>T | 3'UTR (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- GPX5 | c.*312C>T | 3'UTR (SNP) | VAF 91/181 reads (50%) | catalogued as rs966933727; called by muse, mutect2, varscan2
- ID3 | c.*25+107G>T | Intron (SNP) | VAF 15/32 reads (47%) | called by muse, varscan2
- IMPA2 | c.231-1410G>T | Intron (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- KIDINS220 | c.3586-43T>C | Intron (SNP) | VAF 67/117 reads (57%) | called by muse, mutect2, varscan2
- KMO | c.*209A>T | 3'UTR (SNP) | VAF 77/124 reads (62%) | called by muse, mutect2, varscan2
- KMT2C | c.*411T>C | 3'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- LRRC58 | c.*891A>C | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2
- MEIS1 | c.-624_-621del | 5'UTR (DEL) | VAF 77/196 reads (39%) | catalogued as rs944697549; called by pindel, varscan2
- MIPOL1 | c.*626T>A | 3'UTR (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- MMP15 | c.*963G>A | 3'UTR (SNP) | VAF 76/149 reads (51%) | called by muse, mutect2, varscan2
- MND1 | c.*231T>C | 3'UTR (SNP) | VAF 68/130 reads (52%) | called by muse, mutect2, varscan2
- MS4A1 | c.*760A>G | 3'UTR (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- NEK10 | chr3:27110859 T>C | 3'Flank (SNP) | VAF 7/102 reads (7%) | called by muse, mutect2
- NKAIN3 | c.*547T>A | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- NOP58 | c.-40G>C | 5'UTR (SNP) | VAF 31/230 reads (13%) | called by muse, mutect2, varscan2
- PANX1 | c.*1049C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- PASK | c.3333+1122A>T | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- PDE1C | c.1892-11762A>T | Intron (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- PKN1 | c.1885-15C>G | Intron (SNP) | VAF 10/150 reads (7%) | catalogued as rs1485888754; called by muse, mutect2
- PPP2CA | c.*3139C>G | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- PRDM5 | c.*3087T>G | 3'UTR (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- PYGO1 | c.*2928C>T | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- RAB22A | c.*2043G>T | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- RAB2A | c.*1405G>A | 3'UTR (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- RNF217 | c.*5852A>T | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- RYR2 | c.1708+1975G>C | Intron (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2
- SH3TC2 | c.3479-421T>G | Intron (SNP) | VAF 52/94 reads (55%) | called by muse, mutect2, varscan2
- SHPRH | c.*1031G>A | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*8603A>G | 3'UTR (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- SLC22A18AS | c.*35C>T | 3'UTR (SNP) | VAF 87/214 reads (41%) | catalogued as rs1353943167; called by muse, mutect2, varscan2
- SLFNL1 | c.-118-398T>G | Intron (SNP) | VAF 64/115 reads (56%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627429 T>A | 3'Flank (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- SMYD3 | c.531+989T>C | Intron (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- SYNPO2 | c.*109_*110del | 3'UTR (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2
- TC2N | chr14:91779922 T>C | 3'Flank (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- TICRR | c.*421G>C | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- TLR2 | c.*389A>T | 3'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- TMA16 | chr4:163494510 T>C | 5'Flank (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- TP63 | c.1350-4959G>A | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- TPCN2 | c.1539+146C>A | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- TPO | c.*398C>T | 3'UTR (SNP) | VAF 84/170 reads (49%) | called by muse, mutect2, varscan2
- VPS8 | c.480+333G>A | Intron (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- YPEL5 | c.*1480A>T | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- ZGRF1 | c.4697+46A>C | Intron (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- ZNF425 | c.*751T>A | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
